Somatic mutation profile of tumor specimen TCGA-DX-A3U9-01A (aliquot TCGA-DX-A3U9-01A-11D-A307-09) from TCGA case TCGA-DX-A3U9, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 84.9 years (31,010 days).
Specimen TCGA-DX-A3U9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0fa343a-b84e-4579-b229-7f921a50acf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3U9-10A (Blood Derived Normal), aliquot TCGA-DX-A3U9-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e123ded-bd80-4008-9ed2-6d969b002497

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC100868.1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV99226692; called by muse, mutect2
- ARPP21 | c.2191A>T p.T731S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.254); catalogued as COSV99493006; called by muse, mutect2, varscan2
- BOD1L1 | c.8356G>A p.D2786N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99240139; called by muse, mutect2, varscan2
- BRINP2 | c.1674G>C p.K558N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV100838298; called by muse, mutect2, varscan2
- BTNL8 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs778289052, COSV51458332, COSV99180501; called by muse, mutect2, varscan2
- CACNA1H | c.5036A>G p.D1679G | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100673350; called by muse, mutect2, varscan2
- COMP | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV99721552; called by muse, mutect2, varscan2
- CRTC2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57841169, COSV57843903; called by muse, mutect2
- CSMD1 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101224098; called by muse, mutect2, varscan2
- CYP1A2 | c.672T>A p.H224Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV100673934; called by muse, mutect2, varscan2
- DNAJC8 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99746475; called by muse, mutect2, varscan2
- ECT2 | c.970G>C p.E324Q (on ENST00000392692 / NM_001349098.2; = p.E293Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as COSV99221752; called by muse, mutect2, varscan2
- EPHA7 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775779069, COSV65177624; called by muse, mutect2, varscan2
- FRAS1 | c.8543C>T p.P2848L | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53613933, COSV53644938; called by muse, mutect2, varscan2
- FRMD4B | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV101273646; called by muse, mutect2, varscan2
- GALNTL6 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101560433; called by muse, mutect2, varscan2
- HPSE2 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100986027, COSV100986121; called by muse, mutect2, varscan2
- IL10RA | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs564148493, COSV57142748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as rs1270156137, COSV100069092; called by muse, mutect2, varscan2
- LRP1B | c.7432T>A p.L2478M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101259675, COSV67275125; called by muse, mutect2, varscan2
- MASP2 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV99534428; called by muse, mutect2, varscan2
- MYPN | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100590456, COSV62739111; called by muse, mutect2, varscan2
- NIBAN1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762803465, COSV62288287; called by muse, varscan2
- NIBAN1 | c.426C>G p.D142E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100836552; called by muse, varscan2
- OR1S2 | c.141G>C p.M47I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100224346; called by muse, mutect2, varscan2
- OR8A1 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.895); catalogued as COSV99420792; called by muse, mutect2, varscan2
- RTF1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV101048139; called by muse, mutect2, varscan2
- SGO2 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100764775; called by muse, mutect2, varscan2
- SPIC | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs574189804, COSV100163041, COSV54690404; called by muse, mutect2, varscan2
- SRRT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs778413443, COSV61451384; called by muse, mutect2, varscan2
- TPH2 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100422298, COSV61592033; called by muse, mutect2, varscan2
- TTN | c.59110G>A p.E19704K (on ENST00000591111; = p.E12280K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | PolyPhen benign (0.05); catalogued as rs776495338, COSV60242480; called by muse, mutect2, varscan2
- ZBED9 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV101509364; called by muse, mutect2, varscan2
- ZNF180 | c.1038T>G p.N346K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV99660043; called by muse, mutect2, varscan2
- ARHGAP18 | c.946del p.T316Qfs*11 | Frame Shift Del (DEL) | VAF 66/158 reads (42%) | called by mutect2, pindel, varscan2
- HERC1 | c.8474_8478del p.S2825* | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- PALD1 | c.537dup p.Y180Lfs*11 | Frame Shift Ins (INS) | VAF 47/90 reads (52%) | called by mutect2, pindel, varscan2
- CEACAM5 | c.1695C>T p.D565= | Silent (SNP) | VAF 116/202 reads (57%) | catalogued as rs782644830, COSV55751523; called by muse, mutect2, varscan2
- CEP44 | c.399A>G p.Q133= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99639736; called by muse, mutect2, varscan2
- CRB1 | c.2217C>A p.L739= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100958052; called by muse, mutect2, varscan2
- CYP11B1 | c.1179G>A p.Q393= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV52825079, COSV99455565; called by muse, mutect2, varscan2
- DPY19L2 | c.1308A>G p.G436= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV100116924; called by muse, mutect2, varscan2
- FAT2 | c.11778G>T p.L3926= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99943878; called by muse, varscan2
- HS3ST5 | c.57T>A p.L19= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100451259, COSV57152452; called by muse, mutect2, varscan2
- IL36B | c.249T>C p.T83= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV99383043; called by muse, mutect2, varscan2
- IL4R | c.354C>T p.S118= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as rs779320253, COSV50176388; called by muse, mutect2, varscan2
- LPA | c.3870T>A p.V1290= | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as COSV100307810; called by muse, mutect2, varscan2
- OR4D5 | c.669C>T p.V223= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100190145; called by muse, mutect2, varscan2
- PRDM10 | c.2427C>T p.P809= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs145915939; called by muse, mutect2, varscan2
- SLC7A4 | c.573C>G p.S191= | Silent (SNP) | VAF 39/44 reads (89%) | catalogued as COSV100298838; called by muse, mutect2, varscan2
- SNX13 | c.1827C>T p.H609= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV101296872; called by muse, mutect2
- TCHHL1 | c.2589T>C p.L863= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100916588; called by muse, mutect2, varscan2
- TNNT1 | c.189C>T p.F63= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1199222628, COSV52572451; called by muse, mutect2, varscan2
- TTYH1 | c.756G>A p.L252= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV100002368; called by muse, mutect2, varscan2
- ZCCHC3 | c.1194C>T p.T398= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV101210886; called by muse, mutect2, varscan2
- NALCN | c.2193-5737T>C | Intron (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
